Somatic mutation profile of tumor specimen 0D9DQU from CCDI case PBBIRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,395 days).
Specimen 0D9DQU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9b67601-d0a1-493e-9a1f-9bf2765b068d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9DQW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d53db62b-3c31-42c8-8f12-36e7e79f12c5

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Ins 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL17A1 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768387319; called by muse, mutect2
- GPR32 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs779102452, COSV54515423; called by muse, mutect2
- LRAT | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 192/397 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs762455309, COSV60476354; called by muse, mutect2, varscan2
- SCN10A | c.3704C>T p.A1235V | Missense Mutation (SNP) | VAF 224/520 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs765984332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTA1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs370498187; called by muse, mutect2
- TTC38 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 102/451 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745825694, COSV66844367; called by muse, mutect2, varscan2
- VSX2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 174/429 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs138619416; called by muse, mutect2, varscan2
- PDS5A | c.3757dup p.T1253Nfs*3 | Frame Shift Ins (INS) | VAF 48/438 reads (11%) | called by mutect2, varscan2
- RTEL1 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- AASDH | c.318A>G p.L106= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs1027143083; called by muse, mutect2
- ADAD2 | c.285G>A p.P95= | Silent (SNP) | VAF 34/404 reads (8%) | catalogued as rs577200150; called by muse, mutect2
- CCDC120 | c.-13C>T | 5'UTR (SNP) | VAF 80/174 reads (46%) | catalogued as rs372154560, COSV64515071; called by muse, mutect2, varscan2
- MMP9 | c.1750+94T>G | Intron (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2
